Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8162, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8162-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

Patient Name: [REDACTED]

Med: Rec.: [REDACTED]

DOB: [REDACTED]

Client: [REDACTED]

Accession #: [REDACTED]

Phone Number: [REDACTED]

Gender: F

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

[REDACTED]

=====

CLINICAL HISTORY

Right temporal tumor

[REDACTED] TCGA-DU-8162

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, excision biopsy
B: Brain tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right temporal, excision: Anaplastic
oligoastrocytoma (WHO
grade III) (see microscopy description and comment).

COMMENT

Permanent sections confirm the frozen section diagnosis. The sections
contain

hypercellular portions of cerebrum that are moderately to heavily
infiltrated
by a glial neoplastic proliferation. The tumor has an intermixed
oligoastrocytic phenotype. Focally there is brisk mitotic activity,
reaching

7 or greater mitoses per ten high power fields. There is no
microvascular

proliferation or necrosis. The Ki-67 labeling index is up to
approximately 8%.

Positive and negative controls show appropriate immunoreactivity.

No evidence of 1p/19q LOH or MGMT promoter methylation was detected
(see procedure addenda below).

[REDACTED]

=====

PROCEDURES/ADDENDA

[page 2 of 5]
Loss of Heterozygosity 1p, 19q Assay (LOH)
Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No definite evidence of allelic loss on chromosome arm 1p and chromosome arm 19q is detected.
Informative loci are:

Informative loci are: D1S548, D1S1592, D1S552, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from case .
DNA extracted from a corresponding blood specimen was used as a normal reference control. Results should be interpreted with caution as there is significant amount of normal tissue in the background in spite of attempts to microdissect the tumor.

H and E slides were examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 5]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[page 4 of 5]
[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, excision biopsy:

1. Touch prep and smears: Diffusely infiltrating glioma, with abnormal vessels (C/W astrocytoma, R/O other). Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record.

2. Frozen sections: Hypercellular brain tissue with abnormal nuclei (C/W infiltrating glioma). [REDACTED] Frozen section performed at [REDACTED]

and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Right temporal tumor", received fresh, four fragments, 1.5 cm across in aggregate. Semi firm, greyish-white. In total, A1 and A2, A3 frozen tissue.

[REDACTED]

B.

Brain tumor, excision biopsy

CONTAINER LABEL: brain tumor.

FIXATIVE: Formalin. NO. PIECES: multiple. SIZE/VOL: 20x 20 x 4 mm.

CASSETTES: 2, NS.

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent gliofibrillogenesis, zonally. Zonally also, an appreciable population of neoplastic cells over expresses the p53 protein. With the MIB-1 there is a proliferation index that ranges between 5% and 8% in the more active areas.

ICD-9(s):

191.2 191.2

[REDACTED]

[page 5 of 5]
Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
TPS H/E x 1	1		
mGFAP-DA x 1	2		
H/E x 1	2		
LOH-curles x 1	2		
MGMT-slides x 1	2		
MIB1-DA x 1	2		
P53DO7 x 1	2		
H/E x 1	3		

Part B: Brain tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
LOH-slides x 1	2		
MIB1-DA x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 2e64a54b-9eb0-4a92-b3a1-84deca038419 (TCGA-DU-8162.A9F8F064-C21C-4D7E-AE38-5FF6214995BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).